Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A5U6, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A5U6-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report

(For Clinical Use)

ICD-O-3
Carcinoma, squamous cell NOS
8670/3
path
Lower third of esophagus
C15.5
Q4CF Distal third of
esophagus C15.5
JW 4/16/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
	1m 72	☐ Single ☒ Married	Vietnamese	37
Gender	Weight	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☒ Male ☐ Female	60 Kg		15/8	82

HISTORY OF PRESENT ILLNESS
Chief Complaints: Pain, Trouble swallowing
Symptoms: weight loss, Trouble swallowing
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		1 pack / day	24 (yrs)	1/2 (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		1/2 drink / day	38 (yrs)	1/2 (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy	Squamous cell carcinoma	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Esophageal cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T2 N1 M0 Stage: II B		

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
Resection of 112 esophagus		
Primary Tumor		
Organ	Detailed Location	Size
esophageal tumor	lower third	4 x 3 x 2 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T2 N1 M0 Stage: II B		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: __

____ Date:

Time: __

Preserved by: __

____ Date:

Time: __

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
10 min		11 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
esophageal Tumor	4 x 3 x 2 cm	lower third	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₂	N ₁	M ₀	Stage: II B
Notes:			
lymph nodes 2 (positive 1, negative 1)			

[page 5 of 5]
Consolidated Pathology Diagnosis

Histological Pattern										
Cell Distribution			+ -		Structural Pattern			+ -		
Diffuse					Streaming					
Mosaic			X		Storiform					
Necrosis			X		Fibrosis					
Lymphocytic Infiltration			X		Palisading					
Vascular Invasion				X	Cystic Degeneration					
Clusterized			X		Bleeding					
Alveolar Formation				X	Myxoid Change					
Indian File				X	Psammoma/Calcification					

Cellular Differentiation																			
Squamous			+ -		Adenomatous			+ -		Sarcomatous			+ -		Lymphomatous			+ -	
Squamoid Cell			X		Glandular cell					Round Cell					Large Cell				
Spindle Cell			X		Cell Stratification					Fibroblast					Small Cell				
Keratin			X		Secretion					Osteoblast					RS Cell/RS Like				
Desmosome			X		Intracyt. Vacuole					Lipoblast					Inflam. Cell				
Pearl			X		Gland formation					Myoblast					Plasma Cell				

Cellular Differentiation:				☐ Well		☒ Moderate		☐ Poor	
----------------------------------	--	--	--	-------------------------------	--	--	--	-------------------------------	--

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis			X	
Hyperchromatism			X	
Nucleolar Prominent			X	
Multinucleated Giant Cell			X	
Mitotic Activity			X	
Nuclear Grade:			X	

Final Pathology Report

Histological Diagnosis: Squamous cell carcinoma **Grade:** 2

M1: carcinoma metastasizing to LN

Comments:

D1 60% D2 60% D3 50% D4 60%

Neurovascular invasion 1/0

INTEGRATED REPORT OF FINDINGS BY

Date

Case is (check):		

Source: NCI Genomic Data Commons file 4fec8f6e-6ac9-4d32-ba47-2eb657dd0b5a (TCGA-LN-A5U6.E52D8CCE-6A49-4A72-966E-FA396483F0CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).